Gene-level copy-number profile of tumor specimen TCGA-2G-AAI3-01A from TCGA case TCGA-2G-AAI3, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 39.9 years (14,582 days).
Specimen TCGA-2G-AAI3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 70ae1f94-28b5-4525-9bf7-60df21bcb856.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAI3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/b7631b93-1086-4c65-a23a-df73466ac9e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,433; copy number 2: 15,468; copy number 3: 22,402; copy number 4: 17,127; copy number 5: 1,555; copy number 6: 915; copy number 7: 2; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–71,585, 3 genes, copy number 9: OR4G4P, OR4G11P, OR4F5.
- chr12:31,111,652–31,244,685, 2 genes, copy number 7: AC024940.1, AC024940.4.

Autosomal genes at a single copy (total copy number 1): 970. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
